Somatic mutation profile of tumor specimen 0DVVL1 from CCDI case PBCMZC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 8.7 years (3,180 days).
Specimen 0DVVL1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88c69625-87ad-44b9-b60e-13e5156fd0e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVVMC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b4f5223-e1ce-401f-a73d-9c404e29fa69

The open-access MAF lists 48 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, 3'UTR 3, Intron 3, Splice Region 3, 5'Flank 1, 5'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDGFRA | c.2525A>T p.D842V | Missense Mutation (SNP) | VAF 631/1131 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908585, COSV57264120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 189/422 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP13A4 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 51/493 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55068864, COSV99794861; called by muse, mutect2, varscan2
- COL6A5 | c.5216G>A p.R1739Q | Missense Mutation (SNP) | VAF 261/931 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748298425; called by muse, mutect2, varscan2
- DICER1 | c.5439G>T p.E1813D | Missense Mutation (SNP) | VAF 367/854 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as CM160049, COSV58615264, COSV58615771; called by muse, mutect2, varscan2
- FCRL4 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 108/432 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54862273; called by muse, mutect2, varscan2
- FREM2 | c.4492G>A p.A1498T | Missense Mutation (SNP) | VAF 60/791 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99750328; called by muse, mutect2
- OR52E2 | c.953A>T p.E318V | Missense Mutation (SNP) | VAF 55/532 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58611710; called by muse, mutect2
- TUBB2B | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.51); catalogued as rs1215545966; called by muse, mutect2, varscan2
- VCX | c.594C>A p.S198R | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV58231897; called by muse, varscan2
- VCX3B | c.684C>A p.S228R | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.153); catalogued as COSV66842306, COSV66842329; called by muse, varscan2
- ANKRD39 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATF7IP | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 120/1308 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.415); called by muse, mutect2
- C10orf67 | c.437A>T p.D146V (on ENST00000323327; = p.D147V on NM_153714.3) | Missense Mutation (SNP) | VAF 209/822 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK5RAP2 | c.1409A>T p.K470I | Missense Mutation (SNP) | VAF 110/1055 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CEACAM18 | c.651A>T p.E217D | Missense Mutation (SNP) | VAF 104/352 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAH9 | c.4614+1G>A p.X1538_splice | Splice Site (SNP) | VAF 115/219 reads (53%) | called by muse, varscan2
- DOK5 | c.288A>C p.S96= | Splice Region (SNP) | VAF 80/1068 reads (7%) | called by muse, mutect2
- EFCAB14 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 97/920 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHB4 | c.845A>C p.E282A | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ITGA2 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 152/598 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- JPH3 | c.1982A>C p.N661T | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC5AC | c.8990C>T p.T2997I | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious, low confidence (0.03); called by mutect2, varscan2
- MYH15 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 295/1028 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NPIPB15 | c.67-6T>C | Splice Region (SNP) | VAF 34/324 reads (10%) | called by muse, mutect2, varscan2
- PTPRK | c.1848G>T p.L616F | Missense Mutation (SNP) | VAF 139/1115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYNDIG1L | c.-57-5G>T | Splice Region (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 77/283 reads (27%) | called by muse, mutect2, varscan2
- ZNF534 | c.466T>C p.S156P (on ENST00000332323 / NM_001143939.3; = p.S143P on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/361 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZNF681 | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); called by mutect2, varscan2
- ADGRF5 | c.1545A>G p.R515= | Silent (SNP) | VAF 219/790 reads (28%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.1302G>C p.L434= | Silent (SNP) | VAF 116/738 reads (16%) | called by muse, mutect2, varscan2
- CD209 | c.339G>A p.E113= | Silent (SNP) | VAF 111/432 reads (26%) | called by muse, mutect2, varscan2
- GLDC | c.1407T>C p.G469= | Silent (SNP) | VAF 80/779 reads (10%) | catalogued as COSV58676459; called by muse, mutect2, varscan2
- HOMEZ | c.474A>G p.P158= | Silent (SNP) | VAF 160/403 reads (40%) | called by muse, mutect2, varscan2
- MUC19 | c.1617C>T p.N539= | Silent (SNP) | VAF 166/575 reads (29%) | catalogued as rs1377096075; called by muse, mutect2, varscan2
- PRSS27 | c.357G>A p.T119= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs750827030; called by muse, mutect2, varscan2
- PTCHD4 | c.1878G>A p.L626= | Silent (SNP) | VAF 202/718 reads (28%) | called by muse, mutect2, varscan2
- RYR3 | c.7320G>A p.L2440= (on ENST00000389232; = p.L2441= on NM_001036.6) | Silent (SNP) | VAF 228/1005 reads (23%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1344C>T p.I448= | Silent (SNP) | VAF 45/353 reads (13%) | catalogued as rs755885634, COSV56198791; called by muse, mutect2, varscan2
- ABLIM2 | chr4:8158780 G>T | 5'Flank (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- APBB3 | c.626+71T>C | Intron (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- DUSP22 | c.-59C>G | 5'UTR (SNP) | VAF 69/380 reads (18%) | catalogued as rs966037393; called by muse, mutect2, varscan2
- GIT1 | c.761+98C>T | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs1276290446; called by muse, mutect2, varscan2
- GSTM4 | c.113-61C>T | Intron (SNP) | VAF 52/145 reads (36%) | catalogued as rs1036338931; called by mutect2, varscan2
- LONRF3 | c.*11G>T | 3'UTR (SNP) | VAF 61/218 reads (28%) | catalogued as rs748623665, COSV100504424, COSV100504716; called by muse, mutect2, varscan2
- NBL1 | c.*122G>T | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- SLURP2 | c.*96G>C | 3'UTR (SNP) | VAF 46/361 reads (13%) | called by muse, mutect2, varscan2
